Somatic mutation profile of tumor specimen HCM-BROD-0124-C25-01A (aliquot HCM-BROD-0124-C25-01A-01D-A78W-36) from HCMI case HCM-BROD-0124-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 60.5 years (22,096 days).
Specimen HCM-BROD-0124-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da060ea7-b78f-432a-a62f-ca64a2428ac9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0124-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0124-C25-10A-01D-A78W-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f50b98e0-27a1-4e63-9fd8-f656ceb456ce

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 51/295 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSS2 | c.566T>C p.I189T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs768218171; called by muse, varscan2
- ARMH4 | c.2221C>T p.R741* | Nonsense Mutation (SNP) | VAF 45/274 reads (16%) | catalogued as rs375790812; called by muse, mutect2, varscan2
- ATP8A2 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1488656371; called by muse, mutect2
- CDH2 | c.2675C>T p.P892L | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758658207; called by muse, mutect2, varscan2
- CEP170 | c.4706A>G p.N1569S | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.978); catalogued as rs777193870; called by muse, mutect2, varscan2
- KEL | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 71/432 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs767499938; called by muse, mutect2, varscan2
- PLXNA4 | c.3425C>T p.P1142L | Missense Mutation (SNP) | VAF 47/328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753895846; called by muse, mutect2, varscan2
- RNASE9 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100141089; called by muse, mutect2, varscan2
- TP53 | c.997del p.R333Vfs*12 | Frame Shift Del (DEL) | VAF 28/180 reads (16%) | catalogued as CM137619, COSV52774724; called by mutect2, pindel, varscan2
- AP1G2 | c.2329A>G p.N777D | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNNM3 | c.1606T>G p.F536V | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DNAH1 | c.9782delinsCT p.R3261Pfs*58 | Frame Shift Ins (INS) | VAF 31/191 reads (16%) | called by pindel, varscan2*
- GALNT5 | c.2683G>A p.V895M | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GRHL2 | c.891+1G>A p.X297_splice | Splice Site (SNP) | VAF 146/459 reads (32%) | called by muse, varscan2
- HECTD2 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- HTR1B | c.235A>G p.K79E | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF1C | c.2368G>C p.D790H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LRRK2 | c.6895C>T p.P2299S | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MKNK2 | c.1262A>T p.Q421L | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POFUT2 | c.959T>A p.M320K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- STK40 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK20 | c.465C>T p.D155= | Silent (SNP) | VAF 23/242 reads (10%) | catalogued as rs371154514, COSV57482629; called by muse, mutect2
- IGSF8 | c.537G>A p.G179= | Silent (SNP) | VAF 71/439 reads (16%) | called by muse, mutect2, varscan2
- PCDHB3 | c.1965C>T p.T655= | Silent (SNP) | VAF 85/609 reads (14%) | catalogued as rs781913012, COSV50577078; called by muse, mutect2, varscan2
- SCGN | c.306C>T p.N102= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as rs1173035598; called by muse, mutect2
- SNTB1 | c.789-22366T>C | Intron (SNP) | VAF 59/199 reads (30%) | called by muse, mutect2, varscan2
